Somatic mutation profile of tumor specimen 0DU1X8 from CCDI case PBCJES, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.3 years (4,845 days).
Specimen 0DU1X8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b964619-d892-4999-bd40-e55f9c96d916.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU1W7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26dc2ca7-16a0-4e36-b760-2b9973b3e8b4

The open-access MAF lists 17 somatic variants for this specimen: 7 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 7, Missense Mutation 7, Intron 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CARMIL1 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 72/1524 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV61522243; called by muse, mutect2
- ERN1 | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 312/2333 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs757065444, COSV70503330; called by muse, mutect2, varscan2
- MAP3K15 | c.1681G>A p.V561I | Missense Mutation (SNP) | VAF 94/2573 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.029); catalogued as rs375345216; called by muse, mutect2
- CCZ1 | c.647G>A p.S216N | Missense Mutation (SNP) | VAF 131/1704 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- CTNND2 | c.306T>G p.F102L | Missense Mutation (SNP) | VAF 404/1724 reads (23%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- IDS | c.299C>G p.T100S | Missense Mutation (SNP) | VAF 268/1514 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZNF676 | c.722T>A p.F241Y (on ENST00000650058; = p.F209Y on NM_001001411.3) | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- COQ7 | c.237C>T p.V79= | Silent (SNP) | VAF 556/1966 reads (28%) | catalogued as rs778887469; called by muse, mutect2, varscan2
- CRYBG3 | c.6654G>A p.S2218= | Silent (SNP) | VAF 93/2525 reads (4%) | catalogued as rs753867444, COSV99477162; called by muse, mutect2
- DOCK11 | c.1407G>A p.T469= | Silent (SNP) | VAF 278/1012 reads (27%) | catalogued as rs759261269; called by muse, mutect2, varscan2
- FBN3 | c.3852C>T p.C1284= | Silent (SNP) | VAF 552/1843 reads (30%) | catalogued as rs1293942668; called by muse, mutect2, varscan2
- HDAC4 | c.1665C>T p.G555= | Silent (SNP) | VAF 390/1372 reads (28%) | catalogued as rs140175520; called by muse, mutect2, varscan2
- PLB1 | c.963G>A p.E321= | Silent (SNP) | VAF 102/2580 reads (4%) | catalogued as rs781670291; called by muse, mutect2
- POU6F2 | c.639G>A p.S213= | Silent (SNP) | VAF 862/4507 reads (19%) | catalogued as rs770871137; called by muse, mutect2, varscan2
- CEP43 | c.301-89T>C | Intron (SNP) | VAF 14/405 reads (3%) | called by muse, mutect2
- MAP3K19 | c.3222+477G>T | Intron (SNP) | VAF 196/3604 reads (5%) | called by muse, mutect2
- PLEKHO1 | c.-41C>T | 5'UTR (SNP) | VAF 66/617 reads (11%) | called by muse, mutect2, varscan2
